Somatic mutation profile of tumor specimen 0DE0TV from CCDI case PBBNVP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 12.5 years (4,555 days).
Specimen 0DE0TV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e1bf740-5e3e-4528-8b08-e8fe648cba1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE0QN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ca3203a-92e5-4312-ab62-697aefcb7439

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3695G>T p.G1232V | Missense Mutation (SNP) | VAF 36/660 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60798111, COSV60802840; called by muse, mutect2
- FOXD4L5 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as rs754533152, COSV66240626; called by muse, mutect2, varscan2
- FOXD4L4 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 37/372 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NEB | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 90/1305 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RUNX1 | c.654C>T p.P218= (on ENST00000344691 / NM_001001890.3; = p.P245= on NM_001754.5) | Silent (SNP) | VAF 53/688 reads (8%) | catalogued as rs902762123, CD052120; called by muse, mutect2
